Surgical pathology report (de-identified scan), TCGA case TCGA-06-6699, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6699-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

Surgical Pathology Report

TCGA-06-6699

[REDACTED]

CLINICAL HISTORY
Right brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain tumor, excision biopsy
B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, right frontal tumor, excision biopsy: Glioblastoma (WHO Grade IV) (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis of high-grade glioma.

Sections show a moderately pleomorphic, mostly astrocytic neoplasm demonstrating mitotic activity, vascular proliferation, and pseudopalisading

and sheet necrosis. Round oligodendrocyte-like cells are only a minor component. The Ki-67 labeling index is up to approximately 30%.

Positive and

negative controls show appropriate immunoreactivity. Results of additional

studies will be reported in procedure addenda below.

[REDACTED]

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A. Brain, right frontal tumor, excision biopsy: High-grade glioma (some oligodendroglioma features, recommend collect blood for 1p19q analysis).

Frozen section and intraoperative smears performed at [REDACTED] Hospital and

results reported to the Physician of Record. [REDACTED]

[REDACTED]

[page 2 of 2]
GROSS DESCRIPTION

A. Brain tumor, excision biopsy:

CONTAINER LABEL: Brain tumor

FIXATIVE: Fresh. NO. PIECES: 3 tan-brown, glistening tissue fragments.

SIZE/VOL: 2.5 x 2.0 x 0.4 cm, aggregate. CASSETTES: 3, NS with frozen section remnant in cassette 1.

B. Brain, excision biopsy:

CONTAINER LABEL: tumor remnant

FIXATIVE: Fresh. NO. PIECES: multiple tan-pink, hemorrhagic tissue fragments.

SIZE/VOL: 1.2 x 0.8 x 0.6 cm, aggregate. CASSETTES: 1, NS.

ICD-9(s):

237.5 237.5

Histo Data

Part A: Brain tumor, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
FS H/E x 1		1		
H/E x 1		1		
TPS H/E x 1		1		
EGFR VIII-slides x 1		2		
H/E x 1		2		
MGMT-slides x 1		2		
MIB1-DA x 1		2		
x 3		2		
H/E x 1		3		

Part B: Brain, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
H/E x 1		1		

*** End of Report ***

Source: NCI Genomic Data Commons file 258f369b-2285-4b6d-b36c-d8bab59d9d77 (TCGA-06-6699.F4BE21B6-EF74-4A59-B8D1-9A0F76719AB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).